Somatic mutation profile of tumor specimen C3L-00540-59 (aliquot CPT0100710002) from CPTAC case C3L-00540, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 69.0 years (25,217 days).
Specimen C3L-00540-59: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c8f7171-1250-4f14-a08f-60750d5f97fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00540-51 (Buccal Cell Normal), aliquot CPT0100630003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/386bcf45-06a0-4c51-8e11-bb2412e3ebf7

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTN2 | c.1290C>A p.S430R (on ENST00000313400 / NM_001365069.1; = p.S379R on NM_014010.5) | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57774773; called by muse, mutect2, varscan2
- CCDC7 | c.4129C>T p.R1377* | Nonsense Mutation (SNP) | VAF 46/144 reads (32%) | catalogued as rs760860139, COSV56546224; called by muse, mutect2, varscan2
- CNTN5 | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 45/401 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54362652; called by muse, mutect2
- EEF1A2 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 53/678 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs1355004578, COSV53206172; called by muse, mutect2
- IQGAP2 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 36/77 reads (47%) | catalogued as COSV57172729; called by muse, mutect2
- NR4A1 | c.341G>C p.G114A | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs1259640988; called by muse, mutect2
- ANKRD12 | c.5440del p.A1814Qfs*4 | Frame Shift Del (DEL) | VAF 80/170 reads (47%) | called by mutect2, varscan2
- FAM171B | c.561dup p.A188Sfs*2 | Frame Shift Ins (INS) | VAF 48/102 reads (47%) | called by mutect2, varscan2
- NPM1 | c.847-4_859delinsTCCAGGCTATTCAAGATCTCTG p.X283_splice | Splice Site (INS) | VAF 6/74 reads (8%) | called by pindel, varscan2*
- RPS23 | c.291T>A p.N97K | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- MMD | c.642G>A p.T214= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs569360059; called by muse, varscan2
- PRKDC | c.1257C>T p.S419= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs752166512; called by muse, mutect2, varscan2
- SERPINB3 | c.393G>T p.V131= | Silent (SNP) | VAF 99/247 reads (40%) | called by muse, varscan2
